Gene-level copy-number profile of tumor specimen TCGA-FB-AAQ2-01A from TCGA case TCGA-FB-AAQ2, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 81.0 years (29,585 days).
Specimen TCGA-FB-AAQ2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.de4adc0f-4663-4f57-9a4b-2b1bedf02683.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FB-AAQ2-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/85b2616e-a2f6-4012-85d4-afa70bb49eb8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 13,627; copy number 2: 42,360; copy number 3: 2,337; copy number 4: 1,280; copy number 5: 175; copy number 6: 4; copy number 9: 4; copy number 10: 12; copy number 15: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FB-AAQ2-01A-31D-A40V-01): tumor purity 0.33, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:15,481,808–16,758,340, 13 genes (within-gene range 0–1): AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682, SOX6, MIR6073, AC103794.1, AKR1B1P3, RN7SL188P, C11orf58.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 198 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,691,648–42,424,232, 36 genes, copy number 5 (within-gene range 1–5): NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1, AL391730.1, AL391730.2, UBE2V1P8, CTPS1, SLFNL1-AS1, SLFNL1, SCMH1, RPL23AP17, AC093151.7, AC093151.2, AC093151.1, AC093151.5, FOXO6, FOXO6-AS1, RNA5SP45, EDN2, HIVEP3, AL445933.2, AL445933.1, AC119676.1, AL158216.1, HNRNPFP1, AC114492.1, GUCA2B, GUCA2A, FOXJ3, AC096540.1, RIMKLA, AL513331.1.
- chr8:124,973,295–126,008,930, 12 genes, copy number 6–10 (within-gene range 4–10): ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1.
- chr8:126,556,323–127,419,050, 2 genes, copy number 10 (within-gene range 4–15): PCAT1, AC083923.1.
- chr8:126,766,196–127,482,139, 9 genes, copy number 9–15: AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2.
- chr12:66,767–3,593,973, 90 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:14,192,002–16,788,375, 49 genes, copy number 5 (within-gene range 2–5): AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11, ATF7IP, PLBD1, AC008114.1, RN7SKP134, PLBD1-AS1, GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1, PTPRO, AC092183.1, EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP, DERA, EGLN3P1, SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1.

Autosomal genes at a single copy (total copy number 1): 11,206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
